Somatic mutation profile of tumor specimen TCGA-CS-4944-01A (aliquot TCGA-CS-4944-01A-01D-1468-08) from TCGA case TCGA-CS-4944, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 50.6 years (18,494 days).
Specimen TCGA-CS-4944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f415ab2-2ad7-40ea-b8fd-2cfe7e7fb3a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-4944-10A (Blood Derived Normal), aliquot TCGA-CS-4944-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/431c4eb2-67c6-4699-b53c-86eafaf27a89

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CLIP1 | c.4024A>G p.M1342V (on ENST00000620786 / NM_001247997.1; = p.M1331V on NM_002956.2) | Missense Mutation (SNP) | VAF 147/369 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV56804726; called by muse, mutect2, varscan2
- COL18A1 | c.4433G>A p.R1478H (on ENST00000359759 / NM_130444.3; = p.R1243H on NM_030582.4) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs781308033, COSV60590605; called by muse, mutect2, varscan2
- DLX5 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV56033534; called by muse, mutect2, varscan2
- DMKN | c.886A>G p.S296G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1451892931, COSV60087588; called by muse, mutect2, varscan2
- FAM83H | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs572494015, COSV62027497; called by muse, mutect2, varscan2
- GABRG3 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61521074; called by muse, mutect2, varscan2
- LCOR | c.186C>G p.D62E | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV63631490; called by muse, mutect2, varscan2
- OR14A16 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62927013; called by muse, mutect2, varscan2
- SFMBT2 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs199600207, COSV100739559, COSV62812569; called by mutect2, varscan2
- SLC25A36 | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs772683035, COSV60782463; called by muse, mutect2, varscan2
- TSHR | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV53325176; called by muse, mutect2, varscan2
- UGT2A3 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs185390881, COSV52361041; called by muse, mutect2, varscan2
- ZNF12 | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772084571, COSV61244882; called by muse, mutect2, varscan2
- KDM4C | c.2619_2620del p.K873Nfs*36 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- NBPF25P | n.948C>T | Splice Region (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- PIK3R1 | c.292dup p.A98Gfs*8 | Frame Shift Ins (INS) | VAF 28/129 reads (22%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.609A>G p.K203= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs761609152, COSV62014812; called by muse, mutect2, varscan2
- HPR | c.747C>T p.Y249= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs773674981, COSV57183683; called by muse, mutect2, varscan2
- WDR75 | c.105T>C p.S35= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV59106164; called by muse, mutect2, varscan2
